ORGANOID case 3 — Pancreas Cancer Organoid Profiling (ORGANOID-PANCREATIC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/0b2618b5-3ece-4655-b4ed-ed4b51ab6702

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Adenocarcinoma, NOS: Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreas, NOS; AJCC pathologic stage: Stage IIB.

Biospecimens (2 samples)
- Samples S129, S193 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Specimen type: 3D Organoid.
